Somatic mutation profile of tumor specimen MMRF_1646_1_BM_CD138pos (aliquot MMRF_1646_1_BM_CD138pos_T1_KBS5U_K11337) from MMRF case MMRF_1646, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.9 years (30,281 days).
Specimen MMRF_1646_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 304959d8-b279-4062-b43e-0b15cee15c05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1646_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1646_1_PB_Whole_C2_KBS5U_K11338; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e9a8f65-f63a-4e9c-b0e9-e0ff9112bef5

The open-access MAF lists 135 somatic variants for this specimen: 58 protein-altering or splice-affecting, 18 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 35, Silent 18, Intron 10, 5'UTR 5, Nonsense Mutation 4, 3'Flank 4, RNA 4, Splice Site 2, Frame Shift Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BLM | c.3323G>A p.R1108K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100757309, COSV61923505; called by muse, mutect2, varscan2
- CA10 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs1409313336, COSV99562393; called by muse, mutect2, varscan2
- CFHR4 | c.1367A>C p.K456T (on ENST00000367416 / NM_001201551.2; = p.K210T on NM_006684.5) | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as COSV52226389; called by muse, mutect2, varscan2
- CROCC2 | c.4795C>T p.R1599W | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs777136828; called by muse, mutect2, varscan2
- DHX29 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 106/414 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1433193122, COSV52417246; called by mutect2, varscan2
- DYNC1I1 | c.1876G>T p.V626L | Missense Mutation (SNP) | VAF 112/370 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100269153; called by muse, mutect2, varscan2
- EFNA2 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1381677712; called by muse, mutect2, varscan2
- EWSR1 | c.276del p.Y93Mfs*71 | Frame Shift Del (DEL) | VAF 34/96 reads (35%) | catalogued as COSV100131073; called by mutect2, pindel, varscan2
- FAM47E-STBD1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 119/294 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs1201104930; called by muse, mutect2, varscan2
- GPR78 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as rs1336698406, COSV66762392; called by muse, mutect2, varscan2
- HTR1A | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755504345, COSV60500604; called by muse, mutect2, varscan2
- IGHV2-70 | c.320A>T p.D107V | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as rs750213489; called by muse, mutect2, varscan2
- IGLL5 | c.128T>G p.V43G | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs188930549, COSV73251050, COSV73251263; called by muse, mutect2
- IL1RAPL2 | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1249694600; called by muse, mutect2, varscan2
- KCTD9 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55339357; called by muse, mutect2, varscan2
- NRXN1 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1057519409, COSV101278417; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR2Z1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV60692028; called by muse, mutect2, varscan2
- PCF11 | c.1592T>C p.M531T | Missense Mutation (SNP) | VAF 98/302 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1337654642; called by muse, mutect2, varscan2
- PGAP4 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as rs200436453, COSV66388468; called by muse, mutect2
- PREX1 | c.1951G>A p.V651I | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs146847114; called by muse, mutect2, varscan2
- PTK6 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs753348065; called by muse, varscan2
- PTPRS | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.079); catalogued as rs377318412, COSV53610187; called by muse, mutect2, varscan2
- REM1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.196); catalogued as rs548129879; called by muse, mutect2, varscan2
- RPS24 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs558584969; called by muse, mutect2, varscan2
- TNR | c.3244C>T p.R1082C | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs775727703, COSV54886842; called by muse, mutect2, varscan2
- TOGARAM2 | c.1250G>A p.G417D | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1553341369; called by muse, mutect2, varscan2
- TSNAXIP1 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 42/122 reads (34%) | catalogued as rs1413490888, COSV66314887, COSV66315238; called by muse, mutect2, varscan2
- ACACB | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- AMPD2 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP45 | c.2437G>T p.E813* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- BTBD3 | c.415A>G p.K139E | Missense Mutation (SNP) | VAF 81/159 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- BTN3A2 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- CACNA1A | c.4256A>T p.D1419V | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CALN1 | c.340T>C p.F114L (on ENST00000329008 / NM_001017440.3; = p.F156L on NM_031468.4) | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CCDC185 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CD83 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHERP | c.1769G>A p.G590D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- DKKL1 | c.226A>G p.M76V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); called by muse, mutect2
- DNTTIP2 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 113/264 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- DZIP1L | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- GJA8 | c.232T>G p.W78G | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- GRIPAP1 | c.2234G>C p.R745P | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HRNR | c.1201G>C p.G401R | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- KCNAB2 | c.669G>C p.E223D | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KL | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- LRG1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- MAVS | c.347G>T p.R116M | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PARN | c.776A>C p.K259T | Missense Mutation (SNP) | VAF 180/633 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- PCDHGA9 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- POC5 | c.634A>C p.N212H (on ENST00000428202 / NM_001099271.2; = p.N187H on NM_152408.2) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- RHOXF2 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF14 | c.834+2_834+3del p.X278_splice | Splice Site (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- RYR1 | c.13524del p.N4508Kfs*43 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- SIM1 | c.1191A>C p.R397S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TOM1 | c.1408G>C p.G470R | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBR5 | c.8125C>T p.Q2709* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- ZC3H18 | c.1207-2A>G p.X403_splice | Splice Site (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- ZNF574 | c.2003A>C p.E668A | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- ATRNL1 | c.2955A>T p.G985= | Silent (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- CLUH | c.249G>A p.T83= (on ENST00000435359; = p.T121= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as rs761300051; called by muse, mutect2, varscan2
- FASN | c.1473G>A p.P491= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs375957771; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXO2 | c.708C>T p.S236= | Silent (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- GCHFR | c.42G>A p.V14= | Silent (SNP) | VAF 119/202 reads (59%) | catalogued as rs769217835; called by muse, mutect2, varscan2
- GPD1L | c.867G>A p.L289= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- IGHV3-49 | c.294C>T p.S98= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as rs781799113; called by muse, varscan2
- ITK | c.294C>T p.S98= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV101439681; called by muse, mutect2
- MASP2 | c.1149T>G p.P383= | Silent (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- MEGF6 | c.4605C>T p.S1535= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs1204030859, COSV53895356; called by muse, mutect2, varscan2
- MYO9B | c.3516G>A p.E1172= | Silent (SNP) | VAF 34/148 reads (23%) | called by muse, mutect2, varscan2
- NDST3 | c.2436G>A p.L812= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs1020276957; called by muse, mutect2, varscan2
- OPRK1 | c.774C>T p.L258= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV55574748; called by muse, mutect2, varscan2
- OR12D2 | c.600C>A p.V200= | Silent (SNP) | VAF 39/111 reads (35%) | called by muse, mutect2, varscan2
- PKNOX1 | c.207G>A p.L69= | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- QSOX2 | c.465A>C p.G155= | Silent (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- RFTN1 | c.801G>A p.E267= | Silent (SNP) | VAF 55/176 reads (31%) | called by muse, mutect2, varscan2
- SIL1 | c.930C>T p.L310= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs147797471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA10 | c.*432A>C | 3'UTR (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- ABI3BP | c.1064-335A>T | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- AC008676.3 | c.*852A>G | 3'UTR (SNP) | VAF 31/104 reads (30%) | catalogued as rs753221060; called by muse, mutect2, varscan2
- ACKR2 | c.*1531A>C | 3'UTR (SNP) | VAF 6/25 reads (24%) | called by mutect2, varscan2
- AL136982.4 | n.661G>A | RNA (SNP) | VAF 51/93 reads (55%) | catalogued as rs371225899; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852088 C>T | 3'Flank (SNP) | VAF 70/79 reads (89%) | catalogued as rs779052581; called by muse, mutect2, varscan2
- ARHGEF12 | c.-261G>T | 5'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- ASB5 | c.*232T>A | 3'UTR (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- BSDC1 | c.1260+94C>T | Intron (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- C10orf53 | c.*943T>G | 3'UTR (SNP) | VAF 59/116 reads (51%) | called by muse, mutect2, varscan2
- C3orf85 | c.183+13G>A | Intron (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- CA12 | c.*1628G>A | 3'UTR (SNP) | VAF 29/89 reads (33%) | called by muse, mutect2, varscan2
- CEBPA | c.*657C>T | 3'UTR (SNP) | VAF 44/192 reads (23%) | catalogued as rs748249393; called by muse, mutect2, varscan2
- CNTN6 | c.2986+109T>A | Intron (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- DCLK1 | c.*878G>A | 3'UTR (SNP) | VAF 25/61 reads (41%) | catalogued as rs917358817; called by muse, mutect2, varscan2
- DDX12P | n.1472A>C | RNA (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- DNAJB4 | c.*96T>C | 3'UTR (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- DOC2A | c.527+73C>T | Intron (SNP) | VAF 31/51 reads (61%) | called by muse, mutect2, varscan2
- DOC2A | c.343-29C>T | Intron (SNP) | VAF 53/78 reads (68%) | called by muse, mutect2, varscan2
- FAM161A | c.-72C>T | 5'UTR (SNP) | VAF 6/17 reads (35%) | catalogued as rs533836882; called by muse, mutect2, varscan2
- FAM98B | chr15:38486487 T>C | 3'Flank (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- FAU | c.221-162C>G | Intron (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
- GAPT | chr5:58497004 G>A | 3'Flank (SNP) | VAF 59/175 reads (34%) | catalogued as rs1427813674; called by muse, mutect2, varscan2
- GEN1 | c.*103C>T | 3'UTR (SNP) | VAF 43/108 reads (40%) | called by muse, mutect2, varscan2
- GET1 | c.*499G>A | 3'UTR (SNP) | VAF 34/56 reads (61%) | catalogued as rs1277844584; called by muse, mutect2, varscan2
- ITGA8 | c.*1565T>A | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- ITGAV | c.-241_-240insCTT | 5'UTR (INS) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- KIF12 | c.93-38C>T | Intron (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- KIF6 | c.*3577G>A | 3'UTR (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- KNDC1 | c.*1472G>A | 3'UTR (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- KNOP1 | c.*1906G>A | 3'UTR (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- MBOAT7 | c.*406del | 3'UTR (DEL) | VAF 35/182 reads (19%) | called by mutect2, pindel, varscan2
- MIPOL1 | c.*4229C>T | 3'UTR (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- NPTX2 | c.*26C>T | 3'UTR (SNP) | VAF 42/126 reads (33%) | catalogued as rs769767222; called by muse, mutect2, varscan2
- ONECUT2 | c.*1783C>T | 3'UTR (SNP) | VAF 53/116 reads (46%) | called by muse, mutect2, varscan2
- PCDH12 | c.-67C>T | 5'UTR (SNP) | VAF 52/133 reads (39%) | catalogued as rs895206076; called by muse, mutect2, varscan2
- PHAX | c.*858G>T | 3'UTR (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- PITHD1 | c.*398A>C | 3'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- PLA2G4E | c.*145A>G | 3'UTR (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- POLR3A | c.1186-61G>A | Intron (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2
- PTENP1 | n.2528T>A | RNA (SNP) | VAF 277/612 reads (45%) | called by muse, mutect2, varscan2
- PTPN20 | chr10:47000918 A>T | 3'Flank (SNP) | VAF 13/382 reads (3%) | called by muse, mutect2
- RAD51B | c.*1365C>T | 3'UTR (SNP) | VAF 17/46 reads (37%) | catalogued as rs1168890153, COSV66849629; called by muse, varscan2
- REX1BD | c.534-97C>T | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- RIPOR2 | c.*1438G>C | 3'UTR (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- RN7SL342P | chr18:59970885 G>A | 5'Flank (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- RPIA | c.*373C>T | 3'UTR (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- SGTB | c.*1795G>A | 3'UTR (SNP) | VAF 9/52 reads (17%) | catalogued as rs1383437116; called by muse, mutect2, varscan2
- SLC22A11 | c.*1108C>T | 3'UTR (SNP) | VAF 55/147 reads (37%) | catalogued as rs1336687203; called by muse, mutect2, varscan2
- SLC6A19 | c.-21C>T | 5'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as rs370713589; called by muse, mutect2, varscan2
- SOWAHC | c.*1968A>T | 3'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.2751G>A | RNA (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- SRSF4 | c.*663C>G | 3'UTR (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.*2692_*2693dup | 3'UTR (INS) | VAF 26/85 reads (31%) | called by mutect2, pindel, varscan2
- TMEM120B | c.*1505T>C | 3'UTR (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- TRAPPC13 | c.*1203G>T | 3'UTR (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- TRIB1 | c.*1012dup | 3'UTR (INS) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- UBE2W | c.*3983A>T | 3'UTR (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- ZNF439 | c.*702C>T | 3'UTR (SNP) | VAF 25/169 reads (15%) | called by muse, mutect2, varscan2
